MMRF case MMRF_1780 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c99d393e-4a2f-4e8e-8d5d-a7f2ddee68ed

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Dead; Days to death: 849 days (2.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.4 years (23,893 days); ISS stage: III; Days to last known disease status: 849 days (2.3 years); Days to last follow up: 849 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 182 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 259 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 182 days; Days to treatment end: 259 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 259 days; Days to treatment end: 287 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 287 days; Days to treatment end: 552 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 552 days (1.5 years); Days to treatment end: 629 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 559 days (1.5 years); Days to treatment end: 615 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 629 days (1.7 years); Days to treatment end: 644 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 673 days (1.8 years); Days to treatment end: 680 days (1.9 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 673 days (1.8 years); Days to treatment end: 687 days (1.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 849.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.09 mg/dL; Immunoglobulin G 48 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 7.56 µg/mL; Lactate Dehydrogenase 11.4 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 3 mmol/L; Albumin 40 g/L; Total Protein 10.2 g/dL; Glucose 5.39 mmol/L; C-Reactive Protein 1.68 mg/dL.
- Day 77 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 8.32 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 7.38 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 1.98 mmol/L; Albumin 28 g/L; Total Protein 5.9 g/dL; Glucose 5.45 mmol/L.
- Day 182: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 8.51 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.08 mmol/L; Albumin 32 g/L; Total Protein 6 g/dL; Glucose 6.05 mmol/L.
- Day 261: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 8.2 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 6.05 mmol/L.
- Day 371 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.67 mmol/L.
- Day 434: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.56 mg/dL; Immunoglobulin G 16.3 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 6.33 mmol/L.
- Day 552 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.9 mg/dL; Immunoglobulin G 20.6 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 5.01 mmol/L.
- Day 615 (ECOG 1): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.5 mg/dL; Immunoglobulin G 21.6 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.13 mmol/L; Albumin 34 g/L; Total Protein 7.6 g/dL; Glucose 5.89 mmol/L.
- Day 714: Hemoglobin 5.46 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 7.9 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 1.78 mmol/L; Albumin 26 g/L; Total Protein 4.8 g/dL; Glucose 5.34 mmol/L.
- Day 806: Hemoglobin 5.95 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.13 mmol/L; Albumin 27 g/L; Total Protein 7.8 g/dL; Glucose 4.68 mmol/L.

Other clinical attributes
- Day -4: Weight: 118 kg; Height: 187 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1780_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1780_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
